Somatic mutation profile of tumor specimen TCGA-30-1891-01A (aliquot TCGA-30-1891-01A-01W-0699-08) from TCGA case TCGA-30-1891, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 61.2 years (22,344 days).
Specimen TCGA-30-1891-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 695079a4-c8e2-40b6-8ccf-c8f8d4982e7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-30-1891-10A (Blood Derived Normal), aliquot TCGA-30-1891-10A-01W-0699-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f6addf6-7227-4e33-aa3f-b54e13ec783d

The open-access MAF lists 77 somatic variants for this specimen: 62 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 45, Silent 15, Nonsense Mutation 6, Frame Shift Ins 4, Frame Shift Del 4, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 34/77 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 120/438 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV51706596, COSV51716814; called by muse, mutect2, varscan2
- ADAM10 | c.896A>T p.K299M | Missense Mutation (SNP) | VAF 150/252 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53053696; called by muse, mutect2, varscan2
- ARHGAP9 | c.33G>T p.W11C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.436); catalogued as COSV62724067; called by muse, mutect2, varscan2
- BCAN | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 94/280 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as COSV61258652, COSV61259320; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4595C>T p.S1532F | Missense Mutation (SNP) | VAF 84/159 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV63246557; called by muse, mutect2, varscan2
- C11orf49 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as rs759118065, COSV99562539; called by muse, mutect2, varscan2
- CAPN12 | c.92G>C p.S31T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100185458; called by muse, mutect2
- CFAP300 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as COSV71570921; called by muse, mutect2, varscan2
- CFAP58 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.129); catalogued as COSV63835445; called by muse, mutect2, varscan2
- CLDN11 | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as rs772462969, COSV50355903; called by muse, mutect2, varscan2
- CTSC | c.504C>A p.Y168* | Nonsense Mutation (SNP) | VAF 93/282 reads (33%) | catalogued as CM138818, COSV57059453; called by muse, mutect2, varscan2
- DDIAS | c.2065A>T p.I689F | Missense Mutation (SNP) | VAF 163/623 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV61272881; called by muse, mutect2, varscan2
- DDX60L | c.964_990del p.W322_L330del | In Frame Del (DEL) | VAF 35/85 reads (41%) | catalogued as COSV52719059; called by mutect2, pindel
- DNAH3 | c.5846T>A p.L1949H | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.711); catalogued as COSV54540563; called by muse, mutect2, varscan2
- FAM161A | c.648T>G p.D216E | Missense Mutation (SNP) | VAF 105/264 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV56767955; called by muse, mutect2, varscan2
- FARSA | c.1288G>T p.V430L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV53367759; called by muse, mutect2, varscan2
- GRK6 | c.64A>T p.N22Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV62683827; called by muse, mutect2
- HAP1 | c.1200G>C p.M400I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1555589506, COSV57880025; called by muse, mutect2, varscan2
- IL24 | c.508T>A p.F170I | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54321305; called by muse, mutect2, varscan2
- KCTD19 | c.720A>C p.E240D | Missense Mutation (SNP) | VAF 104/271 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV58574296; called by muse, mutect2, varscan2
- KLF17 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.397); catalogued as COSV64856820; called by muse, mutect2, varscan2
- LMAN1L | c.381dup p.L128Afs*12 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs763014383; called by pindel, varscan2
- MAD1L1 | c.807G>T p.L269= | Splice Region (SNP) | VAF 14/22 reads (64%) | catalogued as COSV56243452; called by muse, mutect2, varscan2
- MAGEC2 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 224/603 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV99909799; called by mutect2, varscan2
- MRPL39 | c.883C>G p.R295G | Missense Mutation (SNP) | VAF 110/313 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV56261693; called by muse, mutect2, varscan2
- MT1B | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV57619513; called by muse, mutect2, varscan2
- MUC17 | c.11063C>A p.T3688K | Missense Mutation (SNP) | VAF 99/270 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100075656, COSV60298502; called by muse, mutect2, varscan2
- MYH13 | c.2860C>G p.L954V | Missense Mutation (SNP) | VAF 80/118 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52837697; called by muse, mutect2, varscan2
- MYOC | c.1118G>T p.W373L | Missense Mutation (SNP) | VAF 115/350 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50677091; called by muse, mutect2, varscan2
- NOTCH4 | c.2834G>A p.C945Y | Missense Mutation (SNP) | VAF 67/119 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144858053; called by muse, mutect2, varscan2
- OR6C75 | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 294/761 reads (39%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs1289277934, COSV58553204; called by muse, mutect2, varscan2
- PAOX | c.623T>C p.F208S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV53373819; called by muse, mutect2, varscan2
- PHF20 | c.2447T>A p.V816E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV64977107; called by muse, mutect2, varscan2
- PKHD1L1 | c.508A>T p.T170S | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.817); catalogued as COSV65749411; called by muse, mutect2, varscan2
- PTPRD | c.2349+1G>T p.X783_splice | Splice Site (SNP) | VAF 12/23 reads (52%) | catalogued as COSV61971552; called by muse, mutect2, varscan2
- RUNDC3A | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1162451389, COSV56638653; called by muse, mutect2, varscan2
- RYR2 | c.10413G>C p.K3471N | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV63703882; called by muse, mutect2, varscan2
- SH3BP5 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 26/242 reads (11%) | catalogued as COSV53745827; called by muse, mutect2, varscan2
- SLC38A11 | c.470G>C p.W157S (on ENST00000409149 / NM_001351539.1; = p.W135S on NM_173512.2) | Missense Mutation (SNP) | VAF 268/738 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100366990; called by muse, mutect2, varscan2
- SOWAHC | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV61781375, COSV61781445; called by muse, mutect2, varscan2
- SULT1A1 | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV59090018; called by muse, mutect2, varscan2
- TANC1 | c.4663C>T p.Q1555* | Nonsense Mutation (SNP) | VAF 38/118 reads (32%) | catalogued as COSV55093750; called by muse, mutect2, varscan2
- TM4SF4 | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 162/295 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59516743; called by muse, mutect2, varscan2
- TRA2B | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as rs1303854859, COSV52026108; called by muse, mutect2, varscan2
- TRIM17 | c.821dup p.T275Nfs*14 | Frame Shift Ins (INS) | VAF 9/46 reads (20%) | catalogued as rs758372115; called by mutect2, varscan2
- TSPAN2 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 184/593 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV101050032; called by muse, mutect2, varscan2
- TTN | c.80345G>T p.R26782L (on ENST00000591111; = p.R19358L on NM_003319.4) | Missense Mutation (SNP) | VAF 58/90 reads (64%) | PolyPhen possibly damaging (0.524); catalogued as COSV60243325; called by muse, mutect2, varscan2
- UNC5B | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58979721, COSV58981791; called by muse, mutect2, varscan2
- USP31 | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as COSV54855382; called by muse, mutect2, varscan2
- WEE2 | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 175/358 reads (49%) | catalogued as COSV101187677; called by muse, mutect2, varscan2
- WNK1 | c.5896A>G p.K1966E (on ENST00000315939 / NM_018979.4; = p.K1718E on NM_014823.3) | Missense Mutation (SNP) | VAF 112/427 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV60041828; called by muse, mutect2, varscan2
- WNK3 | c.1466C>T p.T489M | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs373983548, COSV63614592; called by muse, mutect2, varscan2
- YOD1 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 159/277 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.371); catalogued as COSV60006805; called by muse, mutect2, varscan2
- YWHAE | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 124/206 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV51984377; called by muse, mutect2, varscan2
- ZNF79 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 39/128 reads (30%) | catalogued as rs752942190, COSV61071592; called by muse, mutect2, varscan2
- BCORL1 | c.2680_2695del p.S894Rfs*26 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- BTBD16 | c.598_626del p.D200Hfs*60 | Frame Shift Del (DEL) | VAF 10/126 reads (8%) | called by mutect2, pindel
- DST | c.16201_16204dup p.E5402Afs*12 (on ENST00000361203 / NM_001374722.1; = p.E2990Afs*12 on NM_015548.5) | Frame Shift Ins (INS) | VAF 36/155 reads (23%) | called by mutect2, pindel, varscan2
- KLHL38 | c.1574_1599del p.V525Gfs*5 | Frame Shift Del (DEL) | VAF 114/787 reads (14%) | called by mutect2, pindel
- LATS1 | c.233del p.L78Cfs*54 | Frame Shift Del (DEL) | VAF 131/257 reads (51%) | called by mutect2, pindel, varscan2
- SAMD9L | c.1657dup p.V553Gfs*10 | Frame Shift Ins (INS) | VAF 74/222 reads (33%) | called by mutect2, pindel, varscan2
- ANKRD28 | c.1326G>A p.L442= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV67519573; called by muse, mutect2, varscan2
- CARMIL1 | c.1848T>C p.F616= | Silent (SNP) | VAF 97/361 reads (27%) | catalogued as COSV61521896; called by muse, mutect2, varscan2
- CENPJ | c.147C>T p.D49= | Silent (SNP) | VAF 55/118 reads (47%) | catalogued as COSV67883956; called by muse, mutect2, varscan2
- DCAF12L2 | c.186G>T p.A62= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs759758060, COSV63583619; called by muse, mutect2, varscan2
- FKBP8 | c.354C>G p.V118= | Silent (SNP) | VAF 44/143 reads (31%) | catalogued as rs1458692296, COSV55893445; called by muse, mutect2, varscan2
- ITGAM | c.1824G>T p.G608= (on ENST00000648685 / NM_001145808.2; = p.G607= on NM_000632.4) | Silent (SNP) | VAF 68/169 reads (40%) | catalogued as COSV54940635; called by muse, mutect2, varscan2
- KRT12 | c.1152G>C p.L384= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV52431974; called by muse, mutect2, varscan2
- LRRC4C | c.885G>A p.R295= | Silent (SNP) | VAF 148/506 reads (29%) | catalogued as COSV53426177; called by muse, mutect2, varscan2
- LTB4R2 | c.132G>A p.L44= (on ENST00000528054; = p.L13= on NM_019839.5) | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV51867233; called by muse, mutect2, varscan2
- MAPRE3 | c.753C>T p.I251= | Silent (SNP) | VAF 38/146 reads (26%) | catalogued as COSV51868413; called by muse, mutect2, varscan2
- NPC1L1 | c.654C>A p.I218= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs141358485, COSV56928679; called by muse, mutect2, varscan2
- PROKR2 | c.294C>T p.S98= | Silent (SNP) | VAF 91/171 reads (53%) | catalogued as rs146061254; called by muse, mutect2, varscan2
- SCN5A | c.5811C>T p.S1937= (on ENST00000333535 / NM_198056.3; = p.S1936= on NM_000335.5) | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs754276826, COSV61135519; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMAP2 | c.483G>A p.V161= | Silent (SNP) | VAF 50/241 reads (21%) | catalogued as COSV65533323; called by muse, mutect2, varscan2
- STYXL2 | c.2457C>A p.T819= | Silent (SNP) | VAF 57/201 reads (28%) | catalogued as COSV54808515; called by muse, mutect2, varscan2
